Somatic mutation profile of tumor specimen TCGA-D8-A1XQ-01A (aliquot TCGA-D8-A1XQ-01A-11D-A14K-09) from TCGA case TCGA-D8-A1XQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.4 years (25,345 days).
Specimen TCGA-D8-A1XQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96cd8708-d0e4-4330-a29f-ae1670ac2855.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XQ-10A (Blood Derived Normal), aliquot TCGA-D8-A1XQ-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/335dd021-c6d1-4f3e-ac98-f02f3f0a3190

The open-access MAF lists 970 somatic variants for this specimen: 745 protein-altering or splice-affecting, 212 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 547, Silent 212, Frame Shift Del 108, Nonsense Mutation 30, Splice Site 25, Frame Shift Ins 13, In Frame Del 12, Splice Region 8, Intron 6, 5'UTR 3, 3'Flank 2, 5'Flank 1.

Variants (750 of 970; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1708C>T p.R570W (on ENST00000372530 / NM_001198934.2; = p.R527W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/189 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376706540, COSV55085131; called by muse, mutect2, varscan2
- ADSL | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs796052248, COSV53411299; ClinVar: pathogenic; called by muse, mutect2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 19/159 reads (12%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ITGB6 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs730880298, CM142971, COSV99324798; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.754del p.L252Sfs*93 | Frame Shift Del (DEL) | VAF 46/87 reads (53%) | catalogued as rs1555525470, COSV52730003; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCF1 | c.2170A>G p.K724E (on ENST00000326195 / NM_001025091.2; = p.K686E on NM_001090.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV100400946; called by muse, mutect2
- ABR | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV56843647; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 25/219 reads (11%) | catalogued as rs757016425; called by mutect2, varscan2
- ADAMTS13 | c.2989G>T p.G997W | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63023204; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2820A>T p.K940N | Missense Mutation (SNP) | VAF 115/179 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55007668; called by muse, mutect2, varscan2
- ADCY9 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421885899, COSV53581945; called by muse, mutect2, varscan2
- ADGRA3 | c.2582G>A p.C861Y | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51568412; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | catalogued as rs761350619; called by mutect2, varscan2
- AGO3 | c.2423A>G p.H808R | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as COSV55797304; called by muse, mutect2, varscan2
- AGTR1 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770227887, COSV62560196; called by mutect2, varscan2
- AHCTF1 | c.2546G>C p.G849A (on ENST00000366508; = p.G823A on NM_015446.5) | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV58255754; called by muse, mutect2, varscan2
- AIFM3 | c.982A>G p.R328G | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV59004273; called by muse, mutect2, varscan2
- AIM2 | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63702095; called by muse, mutect2, varscan2
- AKAP4 | c.2152G>T p.G718W | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV62075489; called by muse, mutect2, varscan2
- AL645922.1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs764034564, COSV100191332; called by muse, mutect2
- ALAS1 | c.673C>G p.R225G | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as COSV59629716; called by muse, mutect2, varscan2
- ALB | c.29T>A p.L10H | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV55742676; called by muse, mutect2, varscan2
- ALB | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV55742692; called by muse, mutect2, varscan2
- ALMS1 | c.6232C>T p.P2078S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV52522343; called by muse, mutect2, varscan2
- ALPK1 | c.3611T>G p.V1204G | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51592084; called by muse, mutect2, varscan2
- AMDHD1 | c.795C>A p.H265Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as COSV99900425; called by muse, mutect2
- ANAPC5 | c.271A>G p.N91D | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as COSV55841682, COSV55845480; called by muse, mutect2, varscan2
- ANGPT2 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57340455; called by muse, mutect2, varscan2
- ANK1 | c.3103G>A p.G1035R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1001950900, COSV55896136; called by muse, mutect2, varscan2
- ANK2 | c.8978T>G p.I2993R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV52189199; called by muse, mutect2, varscan2
- ANK3 | c.7840C>T p.R2614C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.482); catalogued as rs775291754, COSV99781320; called by muse, mutect2, varscan2
- ANKFN1 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV59451781, COSV59460240; called by muse, mutect2, varscan2
- ANKRD34B | c.412_414del p.L138del | In Frame Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs1351479827; called by pindel, varscan2
- ANKRD35 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100841808; called by muse, mutect2
- ANO4 | c.1162del p.V388Sfs*20 (on ENST00000392977 / NM_001286615.2; = p.V353Sfs*20 on NM_178826.4) | Frame Shift Del (DEL) | VAF 22/164 reads (13%) | catalogued as COSV54613717; called by mutect2, pindel, varscan2
- AOC2 | c.1061C>A p.A354D | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53200361; called by muse, mutect2, varscan2
- APCDD1 | c.165G>T p.M55I | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.62); catalogued as COSV62373384; called by muse, mutect2, varscan2
- APOC3 | c.221G>A p.W74* | Nonsense Mutation (SNP) | VAF 13/205 reads (6%) | catalogued as COSV99369335; called by muse, mutect2
- APOL1 | c.575T>A p.V192D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV59869873; called by muse, mutect2
- ARFGEF1 | c.3121G>C p.G1041R | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51617165; called by muse, mutect2, varscan2
- ARFGEF1 | c.954C>A p.N318K | Missense Mutation (SNP) | VAF 121/402 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51617178; called by muse, mutect2, varscan2
- ARFGEF1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs1350102787, COSV51617193; called by muse, mutect2
- ARFGEF3 | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV52471225; called by muse, mutect2, varscan2
- ARHGAP30 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63515788, COSV63519415; called by muse, mutect2, varscan2
- ARHGEF1 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV61529685; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.626del p.N209Ifs*9 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs1295666772; called by mutect2, pindel
- ARNT | c.1175T>C p.L392S | Missense Mutation (SNP) | VAF 138/185 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62232358; called by muse, mutect2, varscan2
- ASAP1 | c.2503A>G p.K835E | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100727593; called by muse, mutect2
- ASAP1 | c.531T>C p.F177= | Splice Region (SNP) | VAF 48/642 reads (7%) | catalogued as COSV100727594; called by muse, mutect2
- ASCC2 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV57076746; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | catalogued as rs747570359; called by mutect2, varscan2
- ASMTL | c.1645+2T>C p.X549_splice | Splice Site (SNP) | VAF 29/115 reads (25%) | catalogued as COSV101187851; called by muse, mutect2, varscan2
- ASXL1 | c.1220A>G p.H407R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.335); catalogued as COSV60122389; called by muse, mutect2, varscan2
- ATAD2 | c.2392G>A p.V798I | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.148); catalogued as COSV99785057; called by muse, mutect2
- ATG7 | c.1073G>A p.C358Y | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61615751; called by muse, mutect2, varscan2
- ATP13A3 | c.3662C>T p.A1221V (on ENST00000645319 / NM_001367549.1; = p.A1191V on NM_024524.3) | Missense Mutation (SNP) | VAF 54/529 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs773710020, COSV55465165; called by muse, mutect2, varscan2
- ATP13A3 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99757417; called by muse, mutect2
- ATP2C2 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99298418; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1689C>T p.H563= | Splice Region (SNP) | VAF 27/125 reads (22%) | catalogued as rs760603032, COSV59480503; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101215100; called by muse, mutect2
- ATP9A | c.1546C>A p.L516M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58771984; called by muse, mutect2, varscan2
- ATXN1 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV99787116; called by muse, mutect2
- ATXN2 | c.1541C>T p.P514L (on ENST00000550104; = p.P354L on NM_002973.4) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs779112609, COSV66486033; called by muse, mutect2, varscan2
- AURKB | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs749454960, COSV60244122; called by muse, mutect2, varscan2
- AVPR1B | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs782118712, COSV65638670; called by muse, mutect2
- BAZ2B | c.1899A>G p.S633= | Splice Region (SNP) | VAF 7/96 reads (7%) | catalogued as COSV100600833; called by muse, mutect2
- BCAT1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766214085, COSV53917877; called by muse, mutect2, varscan2
- BFSP1 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 49/224 reads (22%) | catalogued as rs1296780837, COSV64901947; called by muse, mutect2, varscan2
- BLOC1S6 | c.224+1G>C p.X75_splice | Splice Site (SNP) | VAF 11/72 reads (15%) | catalogued as COSV55036292, COSV99593359; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 11/100 reads (11%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BOLL | c.160del p.S54Pfs*6 | Frame Shift Del (DEL) | VAF 15/138 reads (11%) | catalogued as rs1428711101, COSV56578902; called by mutect2, pindel, varscan2
- BRINP1 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.539); catalogued as rs151314025, COSV99078587; called by muse, mutect2, varscan2
- BRINP3 | c.1763T>G p.V588G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV66541624; called by muse, mutect2, varscan2
- BRS3 | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV65710967, COSV65711328; called by muse, mutect2, varscan2
- BRWD1 | c.1203A>T p.E401D | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV60902893; called by muse, mutect2, varscan2
- BSN | c.8452A>G p.N2818D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV99609260; called by muse, mutect2, varscan2
- C15orf39 | c.3038C>T p.A1013V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1220436679, COSV62298276; called by muse, mutect2, varscan2
- C2CD3 | c.2795A>G p.Y932C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58101219; called by muse, mutect2, varscan2
- C2orf78 | c.1070del p.N357Mfs*17 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs1242308663; called by mutect2, pindel, varscan2
- C3orf62 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV55540634; called by muse, mutect2, varscan2
- C4orf50 | c.579+1G>T p.X193_splice (on ENST00000324058; = p.X1425_splice on NM_001364689.1 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 32/69 reads (46%) | catalogued as COSV60690776; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 31/183 reads (17%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- C8B | c.1189G>T p.G397C | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748983880, COSV64779713; called by muse, mutect2, varscan2
- C9orf43 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs369075240, COSV99928103; called by muse, mutect2, varscan2
- CA10 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.654); catalogued as COSV53373285; called by muse, mutect2, varscan2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | catalogued as COSV61714509; called by mutect2, pindel, varscan2
- CABLES1 | c.1283T>C p.L428P (on ENST00000256925 / NM_001100619.2; = p.L163P on NM_138375.2) | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV99908163; called by muse, mutect2, varscan2
- CACNA1A | c.6590C>T p.P2197L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs377294817; called by muse, varscan2
- CACNA1E | c.5646G>T p.K1882N | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62425560; called by muse, mutect2, varscan2
- CACNA2D2 | c.2932G>A p.A978T (on ENST00000479441 / NM_001174051.3; = p.A971T on NM_006030.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV56569368; called by muse, mutect2, varscan2
- CACNA2D3 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55582920; called by muse, mutect2, varscan2
- CADM1 | c.1211-2A>C p.X404_splice | Splice Site (SNP) | VAF 10/260 reads (4%) | catalogued as COSV100523109; called by muse, mutect2
- CAMSAP2 | c.4187A>G p.N1396S (on ENST00000236925 / NM_001297707.2; = p.N1385S on NM_203459.3) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV52677526; called by muse, mutect2, varscan2
- CASR | c.2013del p.S672Qfs*28 (on ENST00000490131; = p.S749Qfs*28 on NM_000388.4) | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as COSV56134396; called by mutect2, varscan2
- CBLN2 | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99504522; called by muse, mutect2, varscan2
- CBX8 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53937668; called by muse, mutect2, varscan2
- CCDC63 | c.146A>T p.K49M | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV100370503; called by muse, mutect2
- CCDC68 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs201370562; called by muse, mutect2, varscan2
- CCDC92 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV53022278; called by muse, mutect2, varscan2
- CCDC93 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200247512, COSV60119161, COSV60122319; called by muse, mutect2, varscan2
- CCIN | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs1222018560, COSV58725732; called by muse, mutect2, varscan2
- CCNE2 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 76/440 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.047); catalogued as COSV57377521; called by muse, mutect2, varscan2
- CCP110 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66818190; called by muse, mutect2, varscan2
- CCR1 | c.200del p.N67Tfs*2 | Frame Shift Del (DEL) | VAF 18/170 reads (11%) | catalogued as rs943670629; called by mutect2, pindel
- CD160 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 29/406 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99353542; called by muse, mutect2
- CDC42BPB | c.1466A>G p.K489R | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63476863; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH10 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52571617, COSV52586939, COSV52598182; called by muse, mutect2, varscan2
- CDH11 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV51758291; called by muse, mutect2
- CDK2AP2 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100039446; called by muse, mutect2
- CDK5RAP2 | c.127C>T p.L43= | Splice Region (SNP) | VAF 25/106 reads (24%) | catalogued as rs1564392327, COSV62577835; called by muse, mutect2, varscan2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | catalogued as rs763090473; called by mutect2, varscan2
- CELSR2 | c.2203A>G p.S735G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs1334116691, COSV54779451; called by muse, mutect2, varscan2
- CELSR3 | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as rs1290029544, COSV50911521, COSV51051760; called by muse, mutect2, varscan2
- CENPO | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV99568782; called by muse, mutect2
- CEP112 | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV101210979; called by muse, mutect2, varscan2
- CEP131 | c.2048T>C p.L683S (on ENST00000269392 / NM_001319228.2; = p.L680S on NM_014984.4) | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV53956415; called by muse, mutect2, varscan2
- CEP135 | c.1895T>C p.L632S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV99954726; called by muse, mutect2, varscan2
- CEP152 | c.1285_1287del p.E429del | In Frame Del (DEL) | VAF 16/118 reads (14%) | catalogued as rs1245120931; called by pindel, varscan2
- CEP192 | c.2562T>A p.N854K | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58070775; called by muse, mutect2, varscan2
- CEP20 | c.52A>T p.K18* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV99739942; called by muse, mutect2
- CEP95 | c.2133A>C p.R711S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV73609637; called by muse, mutect2, varscan2
- CFAP58 | c.1094T>C p.V365A | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs777999328, COSV57213628; called by muse, mutect2, varscan2
- CFAP91 | c.1047G>C p.K349N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV56338755; called by muse, mutect2, varscan2
- CFP | c.146dup p.G50Wfs*19 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | catalogued as rs749541242; called by mutect2, pindel
- CHD1L | c.1981A>G p.K661E | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100787539; called by muse, mutect2
- CHD3 | c.5833G>A p.A1945T (on ENST00000330494 / NM_001005273.3; = p.A1911T on NM_005852.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs138945661; called by muse, mutect2
- CHI3L2 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63874928; called by muse, mutect2, varscan2
- CHM | c.1093C>A p.L365I | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63304673; called by muse, mutect2, varscan2
- CHMP4B | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs1372789515, COSV54136381; called by muse, mutect2
- CHORDC1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV57706989; called by muse, mutect2, varscan2
- CHRNA4 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.138); catalogued as rs545104411, COSV64721140; called by muse, varscan2
- CHRNA4 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 63/322 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64721146; called by muse, mutect2, varscan2
- CHRNB2 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765202298, COSV63807902; called by muse, mutect2, varscan2
- CLCA2 | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs1246890467, COSV65288794; called by muse, mutect2, varscan2
- CLDN16 | c.70A>T p.T24S | Missense Mutation (SNP) | VAF 67/728 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53227903; called by muse, mutect2
- CLMN | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs754251662, COSV54188594; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 22/130 reads (17%) | catalogued as rs369752219; called by mutect2, varscan2
- CNOT1 | c.2891G>A p.R964K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.152); catalogued as COSV55320378, COSV55322407; called by muse, mutect2, varscan2
- CNOT6 | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1194342659, COSV56164114; called by muse, mutect2, varscan2
- CNTN6 | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs373831062; called by muse, mutect2, varscan2
- CNTNAP5 | c.691T>G p.L231V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70512606; called by muse, mutect2, varscan2
- COL18A1 | c.3121C>T p.R1041* (on ENST00000359759 / NM_130444.3; = p.R806* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as rs753935209, COSV60593826; called by muse, mutect2, varscan2
- COL22A1 | c.3914C>A p.P1305Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100279666, COSV57342867; called by muse, mutect2
- COL22A1 | c.2870C>T p.A957V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs1269287631, COSV57332041; called by muse, mutect2
- COL4A4 | c.595-1G>T p.X199_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as COSV61636737; called by muse, mutect2, varscan2
- COL4A5 | c.2692del p.M898Wfs*3 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as CD098955; called by mutect2, pindel, varscan2
- COL8A1 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs375350800, COSV53729866; called by muse, mutect2, varscan2
- CORIN | c.1259C>G p.S420* | Nonsense Mutation (SNP) | VAF 25/151 reads (17%) | catalogued as COSV56699540; called by muse, mutect2, varscan2
- COX7A2L | c.298T>C p.Y100H | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52244038; called by muse, mutect2, varscan2
- CRACD | c.3010T>C p.S1004P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV51731675; called by muse, mutect2, varscan2
- CREB3L4 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs371608503; called by muse, mutect2, varscan2
- CREBBP | c.5063C>T p.T1688M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781364836, COSV52127565; called by muse, mutect2, varscan2
- CREBBP | c.2842C>A p.Q948K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.93); catalogued as CM098474, COSV99271042; called by muse, mutect2, varscan2
- CRELD1 | c.157G>C p.V53L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.294); catalogued as COSV55975053; called by muse, mutect2, varscan2
- CRYBG1 | c.3646A>G p.M1216V | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV64814626; called by muse, varscan2
- CSF3R | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58972218; called by muse, mutect2, varscan2
- CSMD1 | c.1139A>T p.Y380F (on ENST00000520002; = p.Y379F on NM_033225.6) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV68261044; called by muse, mutect2, varscan2
- CTTNBP2 | c.3712T>C p.Y1238H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as rs199634048, COSV50477208; called by muse, mutect2, varscan2
- DAAM2 | c.2659G>A p.G887S | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV51420237; called by muse, mutect2, varscan2
- DACH1 | c.1761del p.D587Efs*8 (on ENST00000619232 / NM_001366712.1; = p.D333Efs*8 on NM_004392.6) | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | catalogued as COSV57520064; called by mutect2, pindel, varscan2
- DAO | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as rs952757280, COSV99948778; called by muse, mutect2, varscan2
- DBN1 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV52793228; called by muse, mutect2, varscan2
- DCTN1 | c.3497C>T p.T1166M | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs376549770; called by muse, mutect2, varscan2
- DDX27 | c.2072A>G p.K691R | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs1490408347, COSV65593776, COSV65602451; called by muse, varscan2
- DEFB126 | c.78del p.K26Nfs*3 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as COSV66695085; called by mutect2, pindel, varscan2
- DENND1A | c.1180T>A p.Y394N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV65332665; called by muse, mutect2, varscan2
- DEPDC5 | c.1561T>A p.S521T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.908); catalogued as COSV56711041; called by muse, mutect2, varscan2
- DHTKD1 | c.1849T>C p.Y617H | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV53807071; called by muse, mutect2, varscan2
- DHX35 | c.994T>C p.S332P | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52674616; called by muse, mutect2, varscan2
- DLEC1 | c.2865-2A>G p.X955_splice | Splice Site (SNP) | VAF 16/168 reads (10%) | catalogued as COSV100343037; called by muse, mutect2
- DMAC2 | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55728507; called by muse, mutect2, varscan2
- DNAAF4 | c.338A>G p.E113G | Missense Mutation (SNP) | VAF 57/448 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs373595146; called by muse, mutect2, varscan2
- DNAH17 | c.11678G>T p.G3893V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67761265; called by muse, mutect2, varscan2
- DNAH2 | c.12211C>G p.L4071V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.364); catalogued as COSV66727461; called by muse, mutect2, varscan2
- DNAJB1 | c.545_547del p.K182del | In Frame Del (DEL) | VAF 24/123 reads (20%) | catalogued as rs757193946; called by pindel, varscan2
- DNAJC5B | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52540375; called by muse, mutect2, varscan2
- DOCK9 | c.1567C>T p.P523S (on ENST00000376460 / NM_001366676.2; = p.P524S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59643880; called by muse, mutect2, varscan2
- DOK2 | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV52390218; called by muse, mutect2, varscan2
- DPPA2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101524787; called by muse, mutect2, varscan2
- DPYSL3 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58330790, COSV58330963; called by muse, mutect2, varscan2
- DRC7 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs1250692962, COSV61057860; called by muse, mutect2, varscan2
- DST | c.4874A>G p.K1625R | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV55040379; called by muse, mutect2, varscan2
- DYNC1H1 | c.344+2T>C p.X115_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | catalogued as COSV64142675; called by muse, mutect2, varscan2
- EDEM2 | c.1706T>C p.L569S | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV63259754; called by muse, mutect2, varscan2
- EEA1 | c.1106A>G p.E369G | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100468217; called by muse, mutect2, varscan2
- EEF1G | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 22/290 reads (8%) | catalogued as COSV100240525; called by muse, mutect2
- EFCAB3 | c.686G>A p.C229Y | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.751); catalogued as COSV59500464; called by muse, mutect2
- EFR3A | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1253102043, COSV99603328; called by muse, mutect2
- EIF3D | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99341669; called by muse, mutect2
- EIF4A1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV51512335; called by muse, mutect2, varscan2
- ELF1 | c.1685C>G p.T562R | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV53503078; called by muse, mutect2, varscan2
- EMC9 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.062); catalogued as COSV52825915; called by muse, mutect2, varscan2
- EML3 | c.2086G>C p.A696P | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530217979, COSV99604441; called by muse, mutect2, varscan2
- ENAM | c.1847G>A p.R616K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.347); catalogued as COSV68535497; called by muse, mutect2, varscan2
- ENOSF1 | c.814G>T p.G272C (on ENST00000340116 / NM_001354066.2; = p.G224C on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51895737; called by muse, mutect2, varscan2
- ENOX1 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54919082; called by muse, mutect2, varscan2
- ENTPD8 | c.1131C>G p.I377M | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV58163797; called by muse, mutect2, varscan2
- EOLA2 | c.217A>G p.R73G | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100778090; called by muse, mutect2, varscan2
- EP400 | c.7931C>T p.P2644L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.041); catalogued as rs753667262, COSV57786679; called by muse, mutect2, varscan2
- EPHB1 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV67655060, COSV67671851; called by muse, mutect2, varscan2
- EPHB1 | c.2947A>T p.M983L | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV67671858; called by muse, mutect2, varscan2
- EPHB6 | c.2464C>G p.P822A | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as COSV63893711; called by muse, mutect2, varscan2
- ERCC6 | c.1610G>A p.G537D | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63394470; called by muse, mutect2, varscan2
- EXPH5 | c.4772T>C p.V1591A | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV99761959; called by muse, mutect2
- EXPH5 | c.3916T>C p.S1306P | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as rs1429613135, COSV56208433; called by muse, mutect2
- FADS2 | c.1033A>G p.M345V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV53902542; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM161A | c.1873A>G p.N625D | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV101295711; called by muse, mutect2
- FAM83B | c.1285T>C p.S429P | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as COSV60926971; called by muse, mutect2, varscan2
- FAM83B | c.1286C>A p.S429* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV60920546, COSV60920748; called by muse, mutect2, varscan2
- FAM91A1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 36/562 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100593711; called by muse, mutect2
- FAT3 | c.1120A>G p.I374V | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53175138; called by muse, mutect2, varscan2
- FAT3 | c.10441C>G p.P3481A | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53175166; called by muse, mutect2, varscan2
- FBXO45 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as COSV100291053; called by muse, mutect2
- FCER1A | c.352T>C p.S118P | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100929288; called by muse, mutect2, varscan2
- FCRL3 | c.2110G>C p.A704P | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV63845058; called by muse, varscan2
- FER1L5 | c.4991A>C p.K1664T (on ENST00000623019; = p.K1637T on NM_001293083.2) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV101208891; called by muse, mutect2, varscan2
- FER1L6 | c.2663T>C p.V888A | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1386576176, COSV101206091, COSV67552247; called by muse, mutect2
- FHL3 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs755857737, COSV65952863; called by muse, mutect2, varscan2
- FHOD3 | c.3070G>T p.E1024* (on ENST00000359247 / NM_001281739.3; = p.E1041* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | catalogued as rs1324428548, COSV57189049; called by muse, mutect2, varscan2
- FLG2 | c.3830A>G p.D1277G | Missense Mutation (SNP) | VAF 67/514 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV66173510; called by muse, mutect2, varscan2
- FLNA | c.2132T>C p.V711A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as CM070132, COSV61051870; called by mutect2, varscan2
- FMNL3 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.101); catalogued as COSV53307867; called by muse, mutect2, varscan2
- FMO4 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 49/333 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as rs777570552, COSV63001967; called by muse, mutect2, varscan2
- FOXC1 | c.373A>G p.S125G | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66516686; called by muse, mutect2, varscan2
- FREM1 | c.4478G>T p.G1493V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV66518854, COSV66530265; called by muse, mutect2, varscan2
- FRMPD2 | c.2558T>A p.I853K | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV59723970; called by muse, mutect2, varscan2
- FUT11 | c.124T>G p.W42G | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1265687210, COSV100227053; called by muse, mutect2
- FZD4 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101536063; called by muse, mutect2
- GAGE12J | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 66/685 reads (10%) | catalogued as COSV68163677, COSV68164445; called by muse, varscan2
- GBP3 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV52520054; called by muse, mutect2, varscan2
- GC | c.1395+2T>C p.X465_splice | Splice Site (SNP) | VAF 15/195 reads (8%) | catalogued as COSV99909980; called by muse, mutect2
- GDA | c.920+1G>A p.X307_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as rs771573154, COSV99429531; called by mutect2, varscan2
- GEMIN5 | c.912T>G p.F304L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53565041; called by muse, mutect2, varscan2
- GGA1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs1033425098, COSV57331786; called by muse, mutect2, varscan2
- GGA1 | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57331797; called by muse, mutect2, varscan2
- GJC2 | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs1424515269, COSV100812975; called by muse, mutect2
- GLI3 | c.2422A>C p.I808L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.065); catalogued as COSV67895103; called by muse, mutect2, varscan2
- GNE | c.823A>C p.N275H (on ENST00000396594 / NM_001128227.3; = p.N244H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV64953150; called by muse, mutect2, varscan2
- GOLGA1 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV65221490; called by muse, mutect2, varscan2
- GOLGA1 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV65221493; called by muse, mutect2, varscan2
- GOPC | c.294G>C p.L98F | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV50004733; called by muse, mutect2, varscan2
- GPALPP1 | c.696G>C p.R232S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV62706639; called by muse, mutect2, varscan2
- GPR183 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV100854435, COSV63121728; called by muse, mutect2, varscan2
- GPR22 | c.1286A>G p.Q429R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.005); catalogued as COSV99772703; called by muse, mutect2
- GPRC6A | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100114582; called by muse, mutect2
- GRAMD4 | c.736T>C p.W246R | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as COSV63032741; called by muse, mutect2, varscan2
- GREB1 | c.1202T>G p.V401G | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99303407; called by muse, mutect2, varscan2
- GREB1 | c.4449G>A p.Q1483= | Splice Region (SNP) | VAF 10/63 reads (16%) | catalogued as COSV52196570; called by muse, mutect2, varscan2
- GRIN3A | c.1429A>C p.M477L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV62458395; called by muse, mutect2, varscan2
- GRN | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV50009133; called by muse, mutect2, varscan2
- GSDMA | c.241T>C p.F81L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.621); catalogued as COSV56979861; called by muse, mutect2, varscan2
- H2AC16 | c.4T>A p.S2T | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV58901490; called by muse, mutect2, varscan2
- H2BC1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 54/473 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as rs1226652288, COSV51238611; called by muse, mutect2, varscan2
- H4C13 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as COSV100138003; called by muse, mutect2
- HACE1 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.68); catalogued as rs1156454075, COSV53508086; called by muse, mutect2, varscan2
- HCFC1 | c.3796C>T p.P1266S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100128289, COSV100129553; called by muse, mutect2
- HELLS | c.1840del p.R614Efs*11 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs745837238; called by mutect2, varscan2
- HERC1 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71250306; called by muse, mutect2, varscan2
- HGD | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52201546; called by muse, mutect2, varscan2
- HIRA | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as rs1185401845, COSV54271806; called by muse, mutect2, varscan2
- HLA-C | c.1016-1G>T p.X339_splice | Splice Site (SNP) | VAF 30/224 reads (13%) | catalogued as COSV66119135; called by muse, mutect2, varscan2
- HLTF | c.894+2T>C p.X298_splice | Splice Site (SNP) | VAF 23/204 reads (11%) | catalogued as COSV100027007; called by muse, mutect2, varscan2
- HNRNPA3 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV66821195; called by muse, mutect2, varscan2
- HNRNPK | c.1379G>C p.G460A | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as COSV61091067; called by muse, mutect2, varscan2
- HOXB13 | c.565A>G p.N189D | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.157); catalogued as COSV51707265; called by muse, mutect2, varscan2
- HSF5 | c.1200C>A p.C400* | Nonsense Mutation (SNP) | VAF 39/172 reads (23%) | catalogued as COSV60419759; called by muse, mutect2, varscan2
- HTATSF1 | c.1019G>C p.R340P | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54481355, COSV99511579; called by muse, mutect2, varscan2
- HTR1A | c.293T>G p.V98G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100109199; called by muse, mutect2, varscan2
- HUWE1 | c.7172G>C p.S2391T | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV53364115; called by muse, mutect2, varscan2
- HVCN1 | c.551T>A p.L184H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54374176; called by muse, mutect2, varscan2
- IFIT1 | c.827del p.K276Rfs*16 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as rs1318218502; called by mutect2, pindel, varscan2
- IFT80 | c.1594T>C p.W532R | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100424972; called by muse, mutect2
- IGLL5 | c.313G>C p.V105L | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66539525; called by muse, mutect2, varscan2
- IGSF10 | c.1985T>C p.V662A | Missense Mutation (SNP) | VAF 127/183 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56791871; called by muse, mutect2, varscan2
- IKZF3 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV53107271; called by muse, mutect2, varscan2
- IL1RL2 | c.1130T>C p.I377T | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV51819034; called by muse, mutect2, varscan2
- IL2RA | c.643G>T p.V215F | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56923102; called by muse, mutect2, varscan2
- IMPA2 | c.825G>T p.Q275H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV52321599; called by muse, mutect2, varscan2
- INAVA | c.67del p.E23Rfs*90 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs750421792; called by mutect2, pindel, varscan2
- INMT | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs774371694, COSV50001495; called by muse, mutect2, varscan2
- INO80 | c.532A>G p.K178E | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.074); catalogued as COSV62742848; called by muse, mutect2, varscan2
- INO80D | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as rs373314822; called by muse, mutect2, varscan2
- INPP5B | c.1901C>A p.S634* (on ENST00000373023; = p.S554* on NM_005540.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV65963131; called by muse, mutect2, varscan2
- INTS1 | c.2527del p.R843Gfs*11 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs779930616; called by mutect2, varscan2
- IPO13 | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64895091; called by muse, mutect2, varscan2
- IQSEC3 | c.3082C>G p.L1028V (on ENST00000538872 / NM_001170738.2; = p.L725V on NM_015232.1) | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV58291042; called by muse, mutect2, varscan2
- IREB2 | c.2221C>A p.H741N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99359601; called by muse, mutect2, varscan2
- ITGB1BP1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.185); catalogued as COSV53007183; called by muse, mutect2, varscan2
- ITGB6 | c.2344G>A p.V782I | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs760815776, COSV51798790; called by muse, mutect2, varscan2
- ITIH6 | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54494702; called by muse, mutect2, varscan2
- ITPR2 | c.7343T>C p.M2448T | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV67276268; called by muse, mutect2, varscan2
- ITSN1 | c.2369A>G p.K790R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.268); catalogued as COSV66086143; called by muse, mutect2, varscan2
- IWS1 | c.1123del p.M375Wfs*15 | Frame Shift Del (DEL) | VAF 70/450 reads (16%) | catalogued as rs1558756872; called by mutect2, pindel, varscan2
- IZUMO1 | c.492T>A p.D164E | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV99710987; called by muse, mutect2
- JUP | c.1643A>T p.Q548L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV100159707; called by muse, mutect2
- KCNH6 | c.1634T>C p.L545P | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV59007729; called by muse, mutect2, varscan2
- KCNH8 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs773194583, COSV60455826; called by muse, mutect2, varscan2
- KCNJ2 | c.1121T>C p.F374S | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99696454; called by muse, mutect2
- KDM5B | c.1360T>C p.Y454H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52513034; called by muse, mutect2, varscan2
- KDM6A | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 7/100 reads (7%) | catalogued as COSV65037987; called by muse, mutect2
- KHK | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs199989985, COSV53152031; called by muse, mutect2, varscan2
- KIF15 | c.3787A>C p.M1263L | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV58164788; called by muse, mutect2, varscan2
- KIF5C | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs770716612, COSV68483942; called by muse, mutect2, varscan2
- KIRREL1 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs763921449, COSV63286926, COSV63290072; called by muse, mutect2, varscan2
- KLC1 | c.1496A>G p.D499G | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV55811502; called by muse, mutect2, varscan2
- KLC2 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs752378241, COSV57584388; called by muse, mutect2, varscan2
- KMO | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs771245652, COSV59365542; called by muse, mutect2, varscan2
- KMT2D | c.14613C>G p.S4871R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as COSV56474641; called by muse, mutect2, varscan2
- KMT5B | c.2090_2092del p.K697del | In Frame Del (DEL) | VAF 30/294 reads (10%) | catalogued as rs753470793; called by pindel, varscan2
- LAMA3 | c.3369C>A p.H1123Q | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV58080567; called by muse, varscan2
- LAMB3 | c.2120G>A p.S707N | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.086); catalogued as COSV61918770; called by muse, mutect2
- LAMC1 | c.1724A>G p.Q575R | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99280148; called by muse, mutect2
- LANCL3 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs782120561, COSV66130241; called by muse, mutect2, varscan2
- LCE3D | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.649); catalogued as rs147417899; called by mutect2, varscan2
- LCMT2 | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV59791819; called by muse, mutect2, varscan2
- LDHC | c.992T>G p.I331R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99772616; called by muse, mutect2, varscan2
- LGI1 | c.1197A>T p.L399F | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65059402; called by muse, mutect2, varscan2
- LGI3 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60444408; called by mutect2, varscan2
- LGMN | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58405284; called by muse, mutect2, varscan2
- LHCGR | c.1712T>C p.M571T | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1558797615, COSV54303264; called by muse, mutect2, varscan2
- LHX4 | c.814A>G p.R272G | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55378222; called by muse, mutect2, varscan2
- LILRA4 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs543578213, COSV52493650, COSV52494875; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 37/192 reads (19%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LONRF2 | c.775C>G p.Q259E | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as COSV66542455; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 15/100 reads (15%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP1 | c.6416G>A p.G2139D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54526129; called by muse, mutect2, varscan2
- LRP2 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs543102321, COSV55574897; called by muse, mutect2, varscan2
- LRRC20 | c.449A>T p.N150I (on ENST00000355790 / NM_207119.3; = p.N94I on NM_018205.4) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62939322; called by muse, mutect2, varscan2
- LRRC37A3 | c.4655T>A p.I1552N | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100141307; called by muse, mutect2
- LRRC37A3 | c.4415A>T p.Q1472L | Missense Mutation (SNP) | VAF 59/503 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV58537172; called by muse, mutect2, varscan2
- LRRC8D | c.2104A>G p.I702V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); catalogued as rs771012964, COSV61581291; called by muse, mutect2, varscan2
- LRRIQ3 | c.785A>T p.K262I | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV63050181; called by muse, mutect2, varscan2
- LRRTM1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54443224; called by muse, mutect2, varscan2
- LTBP1 | c.4352A>G p.Y1451C (on ENST00000404816 / NM_206943.4; = p.Y1125C on NM_000627.4) | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55385628; called by muse, mutect2, varscan2
- LVRN | c.698C>G p.A233G | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.378); catalogued as COSV100773595; called by muse, mutect2, varscan2
- LYSMD1 | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 31/740 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100925223; called by muse, mutect2
- MADD | c.4382G>A p.C1461Y | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100211804; called by muse, mutect2, varscan2
- MAGEB4 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV66776663; called by muse, mutect2, varscan2
- MAN2A1 | c.1404del p.F468Lfs*22 | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | catalogued as rs766462976; called by mutect2, pindel, varscan2
- MAN2A2 | c.2885G>T p.R962L | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64639952; called by muse, mutect2, varscan2
- MANSC1 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV67111531; called by muse, mutect2, varscan2
- MAP3K9 | c.1644T>A p.S548R | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101173717; called by muse, mutect2, varscan2
- MARCO | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.409); catalogued as rs371994323; called by muse, mutect2, varscan2
- MARF1 | c.3454G>A p.A1152T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100706149; called by muse, mutect2
- MCM3AP | c.5039-2A>G p.X1680_splice | Splice Site (SNP) | VAF 17/62 reads (27%) | catalogued as COSV52441958; called by muse, mutect2, varscan2
- MCOLN3 | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.301); catalogued as COSV62016096; called by muse, mutect2, varscan2
- MDN1 | c.13967T>C p.L4656S | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101021624; called by muse, mutect2, varscan2
- MGAT4A | c.1340G>A p.G447D | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53850885; called by muse, mutect2, varscan2
- MIPEP | c.887T>A p.V296E | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV66301974; called by muse, mutect2, varscan2
- MKI67 | c.6473A>C p.N2158T | Missense Mutation (SNP) | VAF 56/400 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV64077024; called by muse, mutect2, varscan2
- MKI67 | c.1229A>G p.D410G | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV64077028; called by muse, mutect2, varscan2
- MMS22L | c.2651C>G p.P884R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51526572; called by muse, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 10/72 reads (14%) | catalogued as rs777649506, COSV53202254; called by mutect2, pindel, varscan2
- MPHOSPH9 | c.873-2A>T p.X291_splice | Splice Site (SNP) | VAF 24/176 reads (14%) | catalogued as COSV56624784; called by muse, mutect2, varscan2
- MS4A2 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | catalogued as COSV54013889; called by muse, mutect2, varscan2
- MTBP | c.2536A>G p.S846G | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100012398; called by muse, mutect2
- MTHFR | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.184); catalogued as rs756994487, COSV100453862, COSV57174596; called by muse, mutect2, varscan2
- MTHFR | c.1462A>G p.I488V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1235405305, COSV57174602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTMR11 | c.2089G>A p.A697T (on ENST00000439741 / NM_001145862.2; = p.A625T on NM_181873.3) | Missense Mutation (SNP) | VAF 329/596 reads (55%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV54966934, COSV99641073; called by muse, mutect2, varscan2
- MUC17 | c.6733G>A p.V2245I | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs566889208, COSV60303762; called by muse, mutect2, varscan2
- MUC17 | c.7583C>T p.A2528V | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs1321054164, COSV100074376; called by muse, mutect2
- MUC4 | c.2741G>A p.R914K | Missense Mutation (SNP) | VAF 48/605 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.069); catalogued as COSV100641508; called by muse, mutect2
- MYBPH | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 27/136 reads (20%) | catalogued as rs142613512; called by muse, mutect2, varscan2
- MYCBP2 | c.11143C>T p.R3715* (on ENST00000357337; = p.R3753* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 24/131 reads (18%) | catalogued as COSV62039481; called by muse, mutect2, varscan2
- MYCBP2 | c.6563G>A p.G2188E (on ENST00000357337; = p.G2226E on NM_015057.5) | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100631127; called by muse, mutect2
- MYH10 | c.2330A>G p.H777R | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV52611535; called by muse, mutect2, varscan2
- MYH3 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs749135269, COSV56868171; called by muse, mutect2, varscan2
- MYH4 | c.4544A>T p.D1515V | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55126483; called by muse, mutect2, varscan2
- MYO16 | c.3649G>A p.E1217K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as COSV100696955; called by muse, mutect2, varscan2
- MYO1A | c.733A>G p.R245G | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100271126; called by muse, mutect2, varscan2
- MYO5B | c.3364G>A p.G1122R | Missense Mutation (SNP) | VAF 96/252 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs756171493, COSV53231326; called by muse, mutect2, varscan2
- NAALADL1 | c.1621T>C p.Y541H | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60526107; called by muse, mutect2, varscan2
- NAIP | c.187del p.R63Gfs*2 | Frame Shift Del (DEL) | VAF 26/161 reads (16%) | catalogued as rs760886327, COSV52001917; called by mutect2, pindel, varscan2
- NAPSA | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as COSV53798618, COSV53799176; called by muse, mutect2, varscan2
- NAV1 | c.4885G>A p.D1629N | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.303); catalogued as COSV55226631; called by muse, mutect2, varscan2
- NBEA | c.1226G>C p.G409A | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1392083921, COSV59823380; called by muse, mutect2, varscan2
- NCAPD3 | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101599382; called by muse, mutect2
- NCAPH | c.986G>A p.S329N | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV53638821; called by muse, mutect2, varscan2
- NCL | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 72/379 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.175); catalogued as COSV59547520; called by muse, mutect2, varscan2
- NDUFS2 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as CM109825, COSV57156156; called by muse, mutect2, varscan2
- NEXN | c.1772C>T p.T591I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.17); catalogued as rs775423327, COSV99629235; called by mutect2, varscan2
- NKTR | c.2297del p.N766Ifs*30 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | catalogued as rs767007251; called by mutect2, varscan2
- NLRP1 | c.839A>T p.Q280L | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV52578972; called by muse, mutect2, varscan2
- NLRX1 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs749134937, COSV52709813; called by muse, mutect2
- NOL6 | c.1610T>A p.I537N | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53045978; called by muse, mutect2, varscan2
- NOX1 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 23/132 reads (17%) | catalogued as COSV54196687; called by muse, mutect2, varscan2
- NPAT | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs1384129938, COSV99586223; called by muse, mutect2
- NPEPL1 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1420947341, COSV100622506; called by muse, mutect2
- NRDC | c.116_117del p.S39Cfs*25 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs758367546; called by pindel, varscan2
- NRG2 | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV56840727; called by muse, mutect2, varscan2
- NRXN2 | c.1927C>A p.P643T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.07); catalogued as COSV55463538; called by muse, mutect2, varscan2
- NTNG2 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs775608833, COSV62367789; called by muse, mutect2, varscan2
- NTRK3 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as rs1263462518, COSV100713380; called by muse, mutect2
- NUP160 | c.3223C>A p.L1075I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV65856141; called by muse, mutect2, varscan2
- NUP214 | c.4288A>G p.T1430A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV100845361; called by muse, mutect2, varscan2
- NYNRIN | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); catalogued as COSV66845137; called by muse, mutect2, varscan2
- ODAM | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.121); catalogued as rs1392753832, COSV68572486, COSV68573459; called by muse, mutect2, varscan2
- OGDHL | c.1693A>G p.I565V | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as COSV65104772; called by muse, mutect2, varscan2
- OIT3 | c.556T>C p.C186R | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61827533; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR10A7 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.239); catalogued as rs376446425, COSV58278801; called by muse, mutect2, varscan2
- OR10H1 | c.74T>G p.L25R | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.541); catalogued as rs1192751953, COSV58473114; called by muse, mutect2, varscan2
- OR10J1 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV101419931; called by muse, varscan2
- OR10R2 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 20/182 reads (11%) | catalogued as COSV63768571; called by muse, mutect2
- OR11G2 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1229151429, COSV62132717, COSV62133151; called by muse, mutect2, varscan2
- OR1A2 | c.95del p.L32Cfs*8 | Frame Shift Del (DEL) | VAF 44/227 reads (19%) | catalogued as rs748774437; called by mutect2, pindel, varscan2
- OR1D2 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.11); catalogued as rs1442836242, COSV58922503; called by muse, varscan2
- OR1D2 | c.854A>G p.N285S | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100513938; called by muse, varscan2
- OR2A14 | c.718T>C p.C240R | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV68718680; called by muse, mutect2, varscan2
- OR4B1 | c.168del p.M57Cfs*25 | Frame Shift Del (DEL) | VAF 24/172 reads (14%) | catalogued as COSV58883958; called by pindel, varscan2*
- OR4K13 | c.901del p.R301Dfs*71 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as rs749899868, COSV100237879; called by pindel, varscan2
- OR5B12 | c.128T>A p.M43K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV56906767; called by muse, mutect2, varscan2
- OR5T2 | c.433A>G p.S145G | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100506732, COSV100507002; called by muse, mutect2
- OR6S1 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV57837931; called by muse, mutect2, varscan2
- OR9A4 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71886099; called by muse, mutect2, varscan2
- OSBPL11 | c.38C>A p.S13* | Nonsense Mutation (SNP) | VAF 44/170 reads (26%) | catalogued as COSV56174941, COSV56176511; called by muse, mutect2, varscan2
- OTOGL | c.5021A>T p.N1674I (on ENST00000547103; = p.N1665I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as COSV54023937; called by muse, mutect2, varscan2
- OXA1L | c.556C>T p.Q186* (on ENST00000285848; = p.Q126* on NM_005015.5) | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV53538443; called by muse, mutect2, varscan2
- P2RX4 | c.138G>T p.W46C | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759963161, COSV58742832; called by muse, mutect2, varscan2
- P2RY10 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV50686591; called by muse, mutect2, varscan2
- P3H2 | c.1784A>C p.K595T | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778738955, COSV100078054; called by muse, mutect2, varscan2
- PACS1 | c.1936C>A p.L646M | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57700073; called by muse, mutect2, varscan2
- PACS2 | c.607T>C p.Y203H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.825); catalogued as COSV57657346; called by muse, mutect2, varscan2
- PANX2 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV50315925; called by muse, mutect2, varscan2
- PAQR6 | c.559G>T p.G187* (on ENST00000292291 / NM_001272108.2; = p.G81* on NM_024897.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV52746752; called by muse, mutect2, varscan2
- PC | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63080779, COSV63082565; called by muse, mutect2
- PCBP3 | c.601-2A>T p.X201_splice | Splice Site (SNP) | VAF 25/84 reads (30%) | catalogued as COSV101234355; called by muse, mutect2, varscan2
- PCDH11X | c.2906A>T p.D969V | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53504996; called by muse, mutect2, varscan2
- PCDH15 | c.5057A>G p.K1686R (on ENST00000644397 / NM_001354429.2; = p.K1628R on NM_001142771.2) | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.022); catalogued as COSV64738879; called by muse, mutect2, varscan2
- PCDHA4 | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV63546199; called by muse, mutect2, varscan2
- PCDHA8 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.382); catalogued as COSV100969926, COSV65324031; called by muse, mutect2, varscan2
- PCDHB10 | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.344); catalogued as rs201620449, COSV53383955; called by muse, mutect2, varscan2
- PCDHGB2 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99542911; called by muse, mutect2
- PCF11 | c.4539A>T p.E1513D | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV53537818; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNT | c.7364A>C p.Q2455P | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100855812; called by muse, mutect2, varscan2
- PDE1A | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV59537032; called by muse, mutect2, varscan2
- PDE4B | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752491251, COSV58496374; called by muse, mutect2, varscan2
- PDGFRA | c.3223G>A p.D1075N | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.631); catalogued as rs767697835, COSV57267728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDIA6 | c.171C>A p.H57Q | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55353796; called by muse, varscan2
- PDZK1IP1 | c.137T>C p.I46T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53744675; called by muse, mutect2, varscan2
- PF4V1 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373676570; called by muse, mutect2, varscan2
- PFKP | c.176T>A p.F59Y | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV101127423; called by muse, mutect2, varscan2
- PGAM5 | c.259T>G p.S87A | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV58203039; called by muse, mutect2, varscan2
- PGM5 | c.1098C>G p.F366L | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV67165159; called by muse, mutect2, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | catalogued as rs761575760; called by mutect2, pindel, varscan2
- PIK3R1 | c.1930G>A p.G644S (on ENST00000521381 / NM_181523.3; = p.G374S on NM_181504.4) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57130919, COSV57140018; called by muse, mutect2, varscan2
- PIK3R2 | c.1211A>G p.H404R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV55850337; called by muse, mutect2, varscan2
- PINK1 | c.1538del p.G513Vfs*5 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as CM148018; called by mutect2, pindel, varscan2
- PJA2 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63274705; called by muse, mutect2, varscan2
- PKD1 | c.4858G>A p.A1620T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.136); catalogued as rs376572189; called by mutect2, varscan2
- PKHD1 | c.3124T>C p.S1042P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV61895241; called by muse, mutect2, varscan2
- PLAC8 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV100274573, COSV61048300; called by muse, mutect2, varscan2
- PLCB1 | c.374_376del p.E125del | In Frame Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs766595102; called by pindel, varscan2
- PLEC | c.9095T>C p.V3032A (on ENST00000322810 / NM_201380.4; = p.V2922A on NM_000445.5) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV59696023; called by muse, mutect2, varscan2
- PLEKHH2 | c.2318A>T p.H773L | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV56761415; called by muse, mutect2, varscan2
- PLPPR5 | c.243A>G p.I81M | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV54178833; called by muse, mutect2, varscan2
- PLXNA4 | c.3298G>T p.A1100S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV58157891, COSV58160851; called by mutect2, varscan2
- PMS2 | c.1433G>C p.S478T | Missense Mutation (SNP) | VAF 81/118 reads (69%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56224253; called by muse, mutect2, varscan2
- PNLIPRP2 | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53946871; called by muse, mutect2, varscan2
- PNMA3 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs781793397, COSV64723008; called by muse, mutect2, varscan2
- POLA1 | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.822); catalogued as COSV66890843; called by muse, mutect2, varscan2
- POLE | c.6727G>A p.A2243T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs747349009, COSV57684942, COSV57690922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR1C | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs965467030, COSV100397037; called by muse, mutect2
- POLR3E | c.617T>G p.V206G | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100242278; called by muse, mutect2
- PON1 | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55933993; called by muse, mutect2, varscan2
- POTEE | c.2633T>C p.L878P | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58244890; called by muse, mutect2, varscan2
- POU6F2 | c.2020C>G p.P674A | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.339); catalogued as COSV101302789; called by muse, mutect2, varscan2
- PPFIA2 | c.937A>G p.I313V | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1447169981, COSV61055275; called by muse, mutect2, varscan2
- PPIL2 | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as COSV100622688; called by muse, mutect2
- PPP2R3C | c.292-1G>C p.X98_splice | Splice Site (SNP) | VAF 26/85 reads (31%) | catalogued as COSV54835193; called by muse, mutect2, varscan2
- PPP4R3A | c.1111-2A>C p.X371_splice | Splice Site (SNP) | VAF 15/120 reads (13%) | catalogued as COSV61506614; called by muse, mutect2, varscan2
- PPRC1 | c.3613G>A p.V1205I | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs757322330, COSV53388632; called by muse, mutect2, varscan2
- PPTC7 | c.301T>C p.C101R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62827340; called by muse, mutect2, varscan2
- PRDM2 | c.4739G>A p.R1580K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV52455782; called by muse, mutect2, varscan2
- PRELP | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV58117583; called by muse, mutect2, varscan2
- PRKD1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs368595371, COSV59583304, COSV59583673; called by mutect2, varscan2
- PROX2 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs978709446, COSV71520208; called by muse, mutect2, varscan2
- PRPF40A | c.1665del p.E556Kfs*16 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | catalogued as rs1559093709; called by mutect2, pindel
- PSG2 | c.965-1G>T p.X322_splice | Splice Site (SNP) | VAF 34/182 reads (19%) | catalogued as COSV61546576; called by muse, varscan2
- PSPC1 | c.1414C>A p.P472T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100142493; called by muse, mutect2
- PTCHD3 | c.188A>T p.E63V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as COSV71257281; called by muse, mutect2, varscan2
- PTPRG | c.2559+2T>C p.X853_splice | Splice Site (SNP) | VAF 21/97 reads (22%) | catalogued as rs1479424461, COSV55663134; called by muse, mutect2, varscan2
- PXDNL | c.3082A>G p.R1028G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV62498670; called by muse, mutect2, varscan2
- PXDNL | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV62498067; called by muse, mutect2, varscan2
- PYGB | c.772+2T>C p.X258_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99405300; called by muse, mutect2
- QDPR | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.486); catalogued as rs1225110413, COSV55549434; called by muse, mutect2, varscan2
- RAB40AL | c.679A>G p.M227V | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV54435812; called by muse, mutect2, varscan2
- RALY | c.169T>C p.Y57H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV55784034; called by muse, mutect2, varscan2
- RAPGEF5 | c.1691A>C p.D564A (on ENST00000401957 / NM_001367602.2; = p.D867A on NM_012294.5) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100687525; called by muse, mutect2, varscan2
- RB1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV57325097; called by muse, mutect2, varscan2
- RBKS | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56224532; called by muse, mutect2, varscan2
- RBM4 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.292); catalogued as rs1214593278, COSV100029698; called by muse, mutect2, varscan2
- RC3H1 | c.2668T>C p.Y890H | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV51198619; called by muse, mutect2, varscan2
- RECK | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV65036380; called by muse, mutect2, varscan2
- RELN | c.7048A>G p.T2350A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100634347; called by muse, mutect2
- RGS21 | c.256-2A>G p.X86_splice | Splice Site (SNP) | VAF 14/68 reads (21%) | catalogued as rs1233685634, COSV101314066; called by muse, mutect2, varscan2
- RIC1 | c.3317A>G p.N1106S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99317708; called by muse, mutect2
- RIN3 | c.2467+2T>G p.X823_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99379667; called by muse, mutect2, varscan2
- RIOK1 | c.941T>C p.M314T | Missense Mutation (SNP) | VAF 36/514 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99344876; called by muse, mutect2
- RLF | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV65653246; called by muse, mutect2
- RNASE7 | c.371A>T p.K124M | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as COSV53877781; called by muse, mutect2, varscan2
- RNF128 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV55254671; called by muse, mutect2, varscan2
- RNF168 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 80/932 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100535052; called by muse, mutect2
- RNF20 | c.1582G>T p.D528Y | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV66662414; called by muse, mutect2, varscan2
- RNF43 | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV60419748; called by muse, mutect2, varscan2
- RNF8 | c.1199A>G p.E400G | Missense Mutation (SNP) | VAF 15/291 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100009764; called by muse, mutect2
- ROBO3 | c.3235C>G p.L1079V | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs750145267, COSV67302896; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 37/125 reads (30%) | catalogued as rs752898741; called by mutect2, varscan2
- RP1 | c.1369G>T p.V457L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1210856087, COSV55119765, COSV55127154; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA3 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV101084559, COSV65386723; called by muse, mutect2, varscan2
- RREB1 | c.2088G>C p.E696D | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100619639; called by muse, mutect2
- RTCB | c.736dup p.M246Nfs*6 | Frame Shift Ins (INS) | VAF 22/124 reads (18%) | catalogued as rs771992011; called by mutect2, varscan2
- RUNX1T1 | c.853C>A p.Q285K (on ENST00000265814 / NM_001198628.1; = p.Q258K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/568 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV99753605; called by muse, mutect2
- RUSC2 | c.970C>A p.L324M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100770806; called by muse, mutect2
- RYR3 | c.10075T>C p.Y3359H (on ENST00000389232; = p.Y3360H on NM_001036.6) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs778357889, COSV66808891; called by muse, mutect2, varscan2
- RYR3 | c.12511G>A p.V4171M (on ENST00000389232; = p.V4172M on NM_001036.6) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.122); catalogued as rs377237772; called by muse, mutect2, varscan2
- S100B | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52453592; called by muse, mutect2, varscan2
- SACS | c.2505G>C p.Q835H | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.321); catalogued as COSV66543508, COSV66546888; called by muse, mutect2, varscan2
- SALL3 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73306596; called by muse, mutect2, varscan2
- SAP30 | c.446A>T p.D149V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56635198; called by muse, mutect2, varscan2
- SAXO2 | c.776A>G p.Q259R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV59755440; called by muse, mutect2, varscan2
- SBF1 | c.2516C>T p.T839M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs748349988, COSV100817929; called by muse, mutect2, varscan2
- SCEL | c.1638C>A p.N546K (on ENST00000349847 / NM_144777.3; = p.N526K on NM_003843.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV62994598; called by muse, mutect2, varscan2
- SCLY | c.919A>G p.T307A (on ENST00000651534; = p.T299A on NM_016510.7) | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV54544450; called by muse, mutect2, varscan2
- SCN10A | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769338143, COSV71861262; called by muse, mutect2
- SCN11A | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs778354128, COSV56572068; called by muse, mutect2
- SCN11A | c.131C>A p.T44K | Missense Mutation (SNP) | VAF 84/140 reads (60%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV56578579; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | catalogued as rs768388757; called by mutect2, pindel
- SEMA3A | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV54888378; called by muse, mutect2, varscan2
- SERPINA5 | c.183del p.S62Afs*9 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as COSV61575071; called by mutect2, pindel, varscan2
- SERPINB1 | c.105T>G p.I35M | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV66313920; called by muse, mutect2, varscan2
- SETDB1 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV99645426; called by muse, mutect2
- SF3B2 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs200930603, COSV100488522, COSV59427692; called by muse, mutect2, varscan2
- SF3B3 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV56791120; called by muse, mutect2, varscan2
- SFMBT1 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV99966274; called by muse, mutect2, varscan2
- SHQ1 | c.1078A>G p.K360E | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100345160; called by muse, mutect2
- SI | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs1358892952, COSV100016497; called by muse, mutect2
- SIDT2 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs868396005, COSV54060962; called by muse, mutect2, varscan2
- SIGLEC8 | c.884G>T p.W295L | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV58472750; called by muse, mutect2, varscan2
- SIK3 | c.372G>A p.Q124= (on ENST00000445177 / NM_001366686.2; = p.Q130= on NM_025164.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 36/213 reads (17%) | catalogued as COSV52623345; called by muse, mutect2, varscan2
- SIRPA | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs779342446, COSV61538981; called by muse, mutect2, varscan2
- SKIV2L | c.2332G>C p.D778H | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.157); catalogued as COSV100514792; called by muse, mutect2
- SKIV2L | c.3623G>A p.R1208H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs375183559; called by muse, mutect2
- SLC10A3 | c.77T>C p.L26S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV54837594; called by muse, mutect2, varscan2
- SLC17A9 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as rs749830259, COSV64848304; called by muse, mutect2, varscan2
- SLC25A12 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55533064; called by muse, mutect2, varscan2
- SLC25A32 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99884599; called by muse, mutect2
- SLC26A5 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as COSV59705952; called by muse, mutect2, varscan2
- SLC29A2 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193832496, COSV100237167; called by muse, mutect2
- SLC34A1 | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60998787; called by muse, mutect2, varscan2
- SLC37A1 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV61404753; called by muse, mutect2, varscan2
- SLC38A2 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV56746576; called by muse, mutect2, varscan2
- SLC6A4 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55569817; called by muse, mutect2, varscan2
- SLC6A9 | c.746G>A p.S249N (on ENST00000360584 / NM_201649.4; = p.S195N on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62212166; called by muse, mutect2, varscan2
- SLC9C1 | c.29del p.F10Sfs*11 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | catalogued as rs749004401; called by mutect2, varscan2
- SLFN12 | c.1664A>G p.Y555C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100513163; called by muse, mutect2
- SMAP1 | c.514A>C p.K172Q (on ENST00000370455 / NM_001044305.3; = p.K145Q on NM_021940.5) | Missense Mutation (SNP) | VAF 90/192 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV57645037; called by muse, varscan2
- SMC1A | c.2714T>A p.M905K | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV59131960; called by muse, mutect2, varscan2
- SNAP25 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54775839; called by muse, mutect2, varscan2
- SNIP1 | c.841T>C p.Y281H | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99953219; called by muse, mutect2, varscan2
- SNRNP200 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60494623; called by muse, mutect2, varscan2
- SNRPD2 | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV50004930; called by muse, mutect2, varscan2
- SPAG17 | c.3564A>C p.K1188N | Missense Mutation (SNP) | VAF 95/465 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV60468673; called by muse, mutect2, varscan2
- SPRED1 | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV54439141; called by muse, mutect2, varscan2
- SPTBN4 | c.5422T>A p.W1808R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58959013; called by muse, mutect2, varscan2
- SRGAP2 | c.1634A>T p.E545V (on ENST00000624873 / NM_001170637.4; = p.E546V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55343044; called by muse, mutect2, varscan2
- STAG2 | c.1712T>C p.L571P | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV54372735; called by muse, mutect2, varscan2
- STAT5A | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.461); catalogued as rs1432916053, COSV61808505; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs749477148; called by muse, mutect2, varscan2
- SUPT5H | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.046); catalogued as rs770412349, COSV63242213; called by muse, mutect2, varscan2
- SUV39H1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as rs1211958007, COSV61921408; called by muse, mutect2, varscan2
- SVEP1 | c.4018A>G p.T1340A | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.014); catalogued as COSV57029274; called by muse, mutect2, varscan2
- SVIL | c.5770C>A p.L1924M (on ENST00000355867 / NM_021738.3; = p.L1498M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV63448341; called by muse, mutect2, varscan2
- SYNE1 | c.22520G>A p.R7507H (on ENST00000367255 / NM_182961.4; = p.R7436H on NM_033071.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776733924, COSV55059207; called by muse, mutect2, varscan2
- SYT16 | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746396262, COSV70855775, COSV70857830; called by muse, varscan2
- TACO1 | c.825G>C p.Q275H | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.166); catalogued as COSV51976572; called by muse, mutect2, varscan2
- TANC2 | c.4556del p.P1519Lfs*33 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | catalogued as COSV101267456, COSV67333336; called by mutect2, pindel, varscan2
- TAPT1 | c.1574A>G p.Q525R | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV58824522; called by muse, mutect2, varscan2
- TATDN2 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs779863358, COSV55050469; called by muse, mutect2, varscan2
- TATDN3 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.54); catalogued as COSV65325987; called by muse, mutect2, varscan2
- TBC1D24 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53548901; called by muse, mutect2, varscan2
- TCHH | c.3578A>G p.Q1193R | Missense Mutation (SNP) | VAF 45/342 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.43); catalogued as rs1459799094, COSV64277830; called by muse, mutect2, varscan2
- TDRD6 | c.2552T>A p.F851Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.557); catalogued as COSV60178759; called by muse, mutect2, varscan2
- TENM2 | c.4826T>G p.V1609G (on ENST00000518659 / NM_001122679.2; = p.V1370G on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV69141576; called by muse, mutect2, varscan2
- TEP1 | c.7751G>A p.S2584N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV53000396; called by muse, mutect2, varscan2
- TFAP2C | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52373312; called by muse, mutect2, varscan2
- TFDP1 | c.69T>G p.S23R | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as COSV100945973; called by muse, mutect2
- TGM1 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs143322085; called by muse, mutect2, varscan2
- TIMM8B | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs538340896, COSV54779896; called by muse, mutect2
- TLL1 | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV50325259; called by muse, mutect2, varscan2
- TLR6 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374402826; called by muse, mutect2, varscan2
- TM9SF4 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV54104871; called by muse, mutect2, varscan2
- TMC2 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as rs1181131689, COSV62658476; called by muse, mutect2, varscan2
- TMEM209 | c.1030A>G p.N344D | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV61023690; called by muse, mutect2, varscan2
- TMEM68 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58173200; called by muse, mutect2, varscan2
- TMPRSS11A | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV58361243; called by muse, mutect2, varscan2
- TMPRSS15 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53049326; called by muse, mutect2, varscan2
- TNNI3 | c.56T>C p.I19T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV61279612; called by muse, mutect2, varscan2
- TPO | c.2432C>G p.S811C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61111549; called by muse, mutect2, varscan2
- TPP1 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs778410642, COSV54995391; called by muse, mutect2, varscan2
- TRAF7 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as rs757410464, COSV58218388; called by mutect2, varscan2
- TRIP12 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.768); catalogued as rs373429636; called by muse, mutect2, varscan2
- TRMT112 | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV50008292; called by muse, mutect2, varscan2
- TRPA1 | c.1239del p.C414Vfs*16 | Frame Shift Del (DEL) | VAF 34/279 reads (12%) | catalogued as COSV100085278; called by mutect2, pindel, varscan2
- TRPM2 | c.2122G>A p.V708M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs574190384, COSV55977133, COSV55977278; called by muse, mutect2, varscan2
- TRPM8 | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV61224299; called by muse, mutect2, varscan2
- TRRAP | c.3096G>T p.K1032N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV62838676, COSV62854671; called by muse, mutect2, varscan2
- TSHZ3 | c.1508A>G p.K503R | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.971); catalogued as rs1302681596, COSV53682879; called by muse, mutect2, varscan2
- TSNAXIP1 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV54649584, COSV54652320; called by muse, mutect2, varscan2
- TTN | c.13285T>C p.C4429R (on ENST00000591111; = p.C4383R on NM_003319.4) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | PolyPhen possibly damaging (0.563); catalogued as COSV100622489; called by muse, mutect2
- TUBA3D | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs530707778, COSV58311137; called by muse, mutect2, varscan2
- TWSG1 | c.155A>T p.N52I | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50815827; called by muse, mutect2, varscan2
- UBA7 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61093562; called by muse, mutect2, varscan2
- UBE3B | c.2215A>T p.I739F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV55098896, COSV55100392; called by muse, mutect2, varscan2
- UBN2 | c.2254C>A p.L752I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56035527; called by muse, mutect2, varscan2
- UBQLN1 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 30/100 reads (30%) | catalogued as COSV57409201; called by muse, mutect2, varscan2
- UMODL1 | c.2365G>A p.A789T (on ENST00000408910 / NM_001004416.2; = p.A917T on NM_173568.3) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs375504850, COSV101252650; called by mutect2, varscan2
- UNC79 | c.6806C>G p.A2269G (on ENST00000393151 / NM_001346218.2; = p.A2092G on NM_020818.5) | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99829059; called by muse, mutect2, varscan2
- UPF2 | c.3814C>T p.R1272C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as rs1564331434, COSV62659905; called by muse, mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 13/121 reads (11%) | catalogued as rs747493460; called by mutect2, varscan2
- USP10 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs373590750; called by muse, mutect2, varscan2
- USP26 | c.2563T>C p.F855L | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV63709857; called by muse, mutect2, varscan2
- USP34 | c.9385-2A>G p.X3129_splice | Splice Site (SNP) | VAF 17/118 reads (14%) | catalogued as COSV68402462, COSV68406747; called by muse, mutect2, varscan2
- USP39 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV100083989; called by muse, mutect2, varscan2
- USP39 | c.1235A>G p.Q412R | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60383663; called by muse, mutect2, varscan2
- UTP20 | c.8030A>G p.E2677G | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99882136; called by muse, mutect2, varscan2
- VANGL1 | c.613G>C p.G205R | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as CM127309, COSV100049366, COSV59621369; called by muse, mutect2, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 40/260 reads (15%) | catalogued as rs756863093; called by mutect2, varscan2
- VIL1 | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as rs754252148, COSV50298166; called by muse, mutect2, varscan2
- VPS13A | c.4487G>A p.C1496Y | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as COSV62439371; called by muse, mutect2, varscan2
- VPS36 | c.774+2T>C p.X258_splice | Splice Site (SNP) | VAF 12/143 reads (8%) | catalogued as COSV100955256; called by muse, mutect2
- VWA8 | c.3190T>G p.L1064V | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.918); catalogued as COSV65000605; called by muse, mutect2, varscan2
- WASHC4 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV59892411; called by muse, mutect2, varscan2
- WASL | c.989C>A p.P330Q | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.526); catalogued as COSV56136278; called by muse, mutect2, varscan2
- WDR33 | c.3649T>C p.S1217P | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.012); catalogued as COSV59255613; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs746919573; called by mutect2, varscan2
- WDTC1 | c.1204C>T p.R402* (on ENST00000319394 / NM_001276252.2; = p.R401* on NM_015023.5) | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV60089743; called by muse, mutect2, varscan2
- WFDC5 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV57217674; called by muse, mutect2, varscan2
- XKR4 | c.649T>A p.S217T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.614); catalogued as rs923353549, COSV59339864; called by muse, mutect2, varscan2
- XPO5 | c.1906A>C p.N636H | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV99541217; called by muse, mutect2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 24/156 reads (15%) | catalogued as rs762052135; called by mutect2, varscan2
- XYLT1 | c.1763A>G p.Q588R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs556515927, COSV54496988; called by muse, mutect2, varscan2
- ZBTB41 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100963309; called by muse, mutect2, varscan2
- ZBTB5 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57041878; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | catalogued as rs745875253; called by mutect2, varscan2
- ZNF114 | c.1225A>G p.T409A | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100252107; called by muse, mutect2
- ZNF208 | c.2429G>A p.C810Y | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs918792042, COSV68112717; called by muse, mutect2, varscan2
- ZNF34 | c.1313A>G p.Q438R | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.608); catalogued as COSV100603353; called by muse, mutect2
- ZNF518A | c.861A>C p.E287D | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV60150997, COSV60153387; called by muse, mutect2
- ZNF560 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs267605824, COSV56865944; called by muse, mutect2, varscan2
- ZNF599 | c.1744C>T p.R582* | Nonsense Mutation (SNP) | VAF 17/103 reads (17%) | catalogued as rs1368143032, COSV61397478, COSV61397861; called by muse, mutect2, varscan2
- ZNF76 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.702); catalogued as COSV57355450; called by muse, mutect2, varscan2
- ZNF780A | c.1520G>T p.G507V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61816756; called by muse, mutect2, varscan2
- ZNF793 | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.304); catalogued as COSV71324928, COSV71325194; called by muse, mutect2, varscan2
- ZNF846 | c.1138G>C p.G380R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.487); catalogued as rs756760781, COSV67412674; called by muse, mutect2, varscan2
- ZSWIM3 | c.1175T>C p.M392T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV54851663; called by muse, mutect2, varscan2
- ABL2 | c.2508del p.K836Nfs*34 (on ENST00000502732 / NM_007314.4; = p.K821Nfs*34 on NM_005158.5) | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- ADAL | c.651del p.E218Kfs*33 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, varscan2
- ADGRV1 | c.2648del p.N883Mfs*8 | Frame Shift Del (DEL) | VAF 27/127 reads (21%) | called by mutect2, pindel, varscan2
- ANAPC4 | c.443del p.N148Tfs*67 | Frame Shift Del (DEL) | VAF 20/120 reads (17%) | called by mutect2, pindel, varscan2
- ANO4 | c.1713del p.V572Lfs*5 (on ENST00000392977 / NM_001286615.2; = p.V537Lfs*5 on NM_178826.4) | Frame Shift Del (DEL) | VAF 18/178 reads (10%) | called by mutect2, pindel
- APAF1 | c.3485_3487del p.L1162del (on ENST00000551964 / NM_181861.2; = p.L1108del on NM_001160.3) | In Frame Del (DEL) | VAF 18/145 reads (12%) | called by pindel, varscan2
- APOL5 | c.126_139del p.E44Lfs*12 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- ARID4B | c.1479del p.K493Nfs*18 | Frame Shift Del (DEL) | VAF 39/280 reads (14%) | called by mutect2, pindel, varscan2
- ARMC3 | c.78dup p.A27Sfs*9 | Frame Shift Ins (INS) | VAF 23/158 reads (15%) | called by mutect2, pindel, varscan2
- ASB17 | c.599dup p.L200Ffs*3 | Frame Shift Ins (INS) | VAF 10/100 reads (10%) | called by mutect2, pindel, varscan2
- ATP1A1 | c.74del p.K25Rfs*11 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- BNIP5 | c.1422dup p.L475Sfs*17 | Frame Shift Ins (INS) | VAF 13/134 reads (10%) | called by mutect2, pindel, varscan2
- C2CD3 | c.1429dup p.I477Nfs*12 | Frame Shift Ins (INS) | VAF 22/145 reads (15%) | called by mutect2, varscan2
- CAMSAP2 | c.3359del p.N1120Mfs*4 (on ENST00000236925 / NM_001297707.2; = p.N1109Mfs*4 on NM_203459.3) | Frame Shift Del (DEL) | VAF 38/224 reads (17%) | called by mutect2, pindel, varscan2
- CEACAM18 | c.661_662del p.L221Dfs*16 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by pindel, varscan2
- CECR2 | c.1286del p.K429Rfs*19 (on ENST00000342247 / NM_001290047.2; = p.K246Rfs*19 on NM_001290046.1) | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- CEP55 | c.738del p.D247Ifs*9 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- CLSPN | c.538del p.M180Wfs*7 | Frame Shift Del (DEL) | VAF 50/273 reads (18%) | called by mutect2, pindel, varscan2
- CNBD2 | c.1409del p.K470Sfs*3 (on ENST00000373973 / NM_001365709.1; = p.K466Sfs*3 on NM_080834.4) | Frame Shift Del (DEL) | VAF 11/116 reads (9%) | called by mutect2, pindel
- COL19A1 | c.2027del p.P676Qfs*31 | Frame Shift Del (DEL) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- COL5A3 | c.1111_1147del p.G371* | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | called by mutect2, pindel
- CRYBG1 | c.3718del p.S1240Vfs*21 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by pindel, varscan2
- CYBRD1 | c.649del p.W217Gfs*2 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | called by mutect2, pindel, varscan2
- DMXL1 | c.1229del p.L410Yfs*17 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- DNAH8 | c.5314del p.M1772Cfs*12 | Frame Shift Del (DEL) | VAF 15/138 reads (11%) | called by mutect2, pindel, varscan2
- EIPR1 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2
- EMC3 | c.271dup p.T91Nfs*2 | Frame Shift Ins (INS) | VAF 18/100 reads (18%) | called by mutect2, varscan2
- EPB41L3 | c.519del p.K173Nfs*14 | Frame Shift Del (DEL) | VAF 19/167 reads (11%) | called by mutect2, pindel, varscan2
- EXOSC2 | c.125del p.X42_splice | Splice Site (DEL) | VAF 29/122 reads (24%) | called by mutect2, pindel, varscan2
- EZH2 | c.589_590del p.E197Rfs*12 | Frame Shift Del (DEL) | VAF 26/162 reads (16%) | called by pindel, varscan2
- FAM168B | c.517del p.H173Tfs*63 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel
- FANCF | c.880dup p.W294Lfs*5 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel, varscan2
- FCGBP | c.8438A>G p.H2813R | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FNDC3A | c.1645del p.S549Vfs*6 (on ENST00000492622 / NM_001079673.2; = p.S493Vfs*6 on NM_014923.5) | Frame Shift Del (DEL) | VAF 15/95 reads (16%) | called by mutect2, pindel, varscan2
- FOXC2 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); called by muse, mutect2
- FOXD4L4 | c.263C>A p.T88N | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- FURIN | c.547dup p.Q183Pfs*9 | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- GALNT12 | c.1209del p.L404Wfs*7 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel*, varscan2
- GALNTL6 | c.1700_1702del p.K567del | In Frame Del (DEL) | VAF 24/104 reads (23%) | called by pindel, varscan2
- GRB14 | c.839del p.F280Sfs*40 | Frame Shift Del (DEL) | VAF 15/101 reads (15%) | called by mutect2, pindel, varscan2
- GSR | c.1259del p.P420Lfs*18 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | called by mutect2, pindel, varscan2
- HCAR2 | c.298del p.C100Afs*3 | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- ICE1 | c.3149_3170del p.K1050Mfs*53 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- IGF2BP2 | c.497del p.P166Lfs*49 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | called by mutect2, pindel
- IGHV3-53 | c.26del p.F9Sfs*22 | Frame Shift Del (DEL) | VAF 31/251 reads (12%) | called by mutect2, varscan2
- IGHV3-7 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KCTD3 | c.1561del p.R521Efs*18 | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | called by mutect2, pindel, varscan2
- KIAA0319L | c.399del p.K133Nfs*22 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel
- LRP2 | c.2298del p.F766Lfs*46 | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- MNT | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by mutect2, varscan2
- MOSPD2 | c.878del p.K293Rfs*21 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- MTIF2 | c.1154_1155del p.S385Cfs*16 | Frame Shift Del (DEL) | VAF 24/182 reads (13%) | called by pindel, varscan2
- NBEA | c.2561dup p.N854Kfs*18 | Frame Shift Ins (INS) | VAF 13/125 reads (10%) | called by mutect2, pindel
- NEXN | c.717del p.E240Nfs*8 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- NIN | c.2021dup p.N674Kfs*2 | Frame Shift Ins (INS) | VAF 6/66 reads (9%) | called by mutect2, pindel
- NOTCH1 | c.7386del p.A2463Pfs*14 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- NPVF | c.206del p.N69Mfs*5 | Frame Shift Del (DEL) | VAF 27/129 reads (21%) | called by mutect2, pindel, varscan2
- NUP85 | c.1693_1695del p.T565del | In Frame Del (DEL) | VAF 39/108 reads (36%) | called by mutect2, pindel, varscan2
- OGFRL1 | c.1052del p.N351Ifs*8 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- OTOR | c.186del p.Q64Sfs*10 | Frame Shift Del (DEL) | VAF 37/150 reads (25%) | called by mutect2, pindel, varscan2
- OTUD7A | c.1183del p.L395* (on ENST00000307050 / NM_001382637.1; = p.L388* on NM_130901.3) | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- PAK5 | c.1926dup p.Y643Lfs*4 | Frame Shift Ins (INS) | VAF 26/100 reads (26%) | called by mutect2, pindel, varscan2
- PARGP1 | n.1202_1204del | Splice Region (DEL) | VAF 9/74 reads (12%) | called by mutect2, pindel, varscan2
- PAXBP1 | c.840_851del p.S281_Q284del | In Frame Del (DEL) | VAF 19/147 reads (13%) | called by mutect2, pindel, varscan2
- PEAR1 | c.1979del p.N660Tfs*25 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by pindel, varscan2*
- PER2 | c.2606del p.P869Rfs*150 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by pindel, varscan2
- PNRC1 | c.978_*6del | Nonstop Mutation (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- PRODH2 | c.1050G>T p.Q350H (on ENST00000301175; = p.Q274H on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PROX1 | c.126del p.F42Lfs*4 | Frame Shift Del (DEL) | VAF 25/205 reads (12%) | called by mutect2, pindel, varscan2
- PRSS45P | c.627_638del p.C210_A213del | In Frame Del (DEL) | VAF 24/198 reads (12%) | called by mutect2, pindel
- RCBTB2 | c.103del p.S35Pfs*10 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- RING1 | c.965del p.G322Afs*54 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- SAFB2 | c.340-6_368del p.X114_splice | Splice Site (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel
- SCN2B | c.408_416del p.R137_H139del | In Frame Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel
- SLC10A5 | c.866_867del p.I289Sfs*5 | Frame Shift Del (DEL) | VAF 228/335 reads (68%) | called by mutect2, pindel, varscan2
- SLTM | c.3071_3089del p.K1024Ifs*16 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel
- TENT5D | c.261del p.F87Lfs*19 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | called by mutect2, pindel, varscan2
- THADA | c.998_1010del p.L333Hfs*7 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.275del p.P92Lfs*6 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- TPRG1L | c.666del p.A223Pfs*15 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | called by mutect2, pindel, varscan2
- U2SURP | c.1981del p.A661Qfs*8 | Frame Shift Del (DEL) | VAF 89/246 reads (36%) | called by mutect2, pindel, varscan2
- VRK2 | c.142_144delinsTCCG p.P48Sfs*4 | Frame Shift Ins (INS) | VAF 23/228 reads (10%) | called by pindel, varscan2*
- WWC2 | c.2730del p.E911Rfs*16 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- ZNF471 | c.1483_1484del p.A495Ffs*2 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, varscan2*
- ZRANB3 | c.2130_2132del p.E710del | In Frame Del (DEL) | VAF 39/204 reads (19%) | called by pindel, varscan2
- ABCB5 | c.153T>C p.G51= | Silent (SNP) | VAF 33/200 reads (17%) | catalogued as COSV68862027; called by muse, mutect2, varscan2
- ACTN4 | c.2274C>T p.D758= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs767071822, COSV53150864; called by mutect2, varscan2
- ADCY4 | c.1176T>C p.D392= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100156730; called by mutect2, varscan2
- ADGRG4 | c.507C>T p.S169= | Silent (SNP) | VAF 24/172 reads (14%) | catalogued as rs1179178286, COSV54966936; called by muse, mutect2, varscan2
- ADPRHL1 | c.30G>A p.L10= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV60262676; called by muse, mutect2, varscan2
220 further variants in this file (0 protein-altering or splice-affecting, 207 silent, 13 other) are not listed here.
